Somatic mutation profile of tumor specimen TCGA-S7-A7X0-01A (aliquot TCGA-S7-A7X0-01A-12D-A35I-08) from TCGA case TCGA-S7-A7X0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 75.9 years (27,729 days).
Specimen TCGA-S7-A7X0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f543458-0664-4892-8aef-b6a6a02b495a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7X0-10A (Blood Derived Normal), aliquot TCGA-S7-A7X0-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8aac0d7-479a-43eb-b221-f719f38d4189

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1591C>G p.P531A | Missense Mutation (SNP) | VAF 38/117 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55384498, COSV55386554, COSV55388056; called by muse, mutect2, varscan2
- BSN | c.6173T>G p.M2058R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1323057612; called by muse, mutect2
- IFT122 | c.2128G>A p.A710T (on ENST00000348417 / NM_052989.3; = p.A651T on NM_018262.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56206184; called by muse, mutect2
- ILF3 | c.2567C>T p.S856L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs767690509; called by muse, mutect2
- ITGAM | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs1273881021, COSV54942971; called by muse, mutect2, varscan2
- LRRC3 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs567420098, COSV52398785; called by muse, mutect2, varscan2
- MLH3 | c.3452C>T p.A1151V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1555344011; ClinVar: uncertain significance; called by muse, mutect2
- AKAP8L | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- C4orf19 | c.26T>A p.I9K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GPATCH8 | c.3290T>G p.I1097S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2
- GTSE1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-43 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- JADE2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- OR2L2 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CARD11 | c.703C>A p.R235= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV67796876, COSV67800219; called by muse, mutect2, varscan2
- DNAH5 | c.8190G>A p.T2730= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as rs752656841, COSV54229634; ClinVar: likely benign; called by muse, mutect2
- HSPG2 | c.11442C>T p.S3814= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs562275583; called by mutect2, varscan2
- SSH1 | c.735C>T p.P245= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs1306017785; called by mutect2, varscan2
